Gene-level copy-number profile of tumor specimen ALCH-B1MZ-TTP1-A from ALCHEMIST case ALCH-B1MZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.1 years (23,042 days).
Specimen ALCH-B1MZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cabea2f6-98d1-4b86-9d5a-6dc364db7de0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1MZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/b04caf4a-c6a9-4ee2-8cb5-fd52bfb51502

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 27,509; copy number 2: 28,638; copy number 3: 1,633; copy number 4: 138; copy number 5: 305; copy number 6: 150; copy number 7: 2; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,441,096–7,441,554, 1 gene (within-gene range 0–1): CAMTA1-AS1.
- chr2:242,087,351–242,088,457, 1 gene: AC093642.2.
- chr3:14,394,648–14,489,349, 2 genes (within-gene range 0–1): RNA5SP124, SLC6A6.
- chr5:175,658,030–175,710,756, 1 gene (within-gene range 0–1): HRH2.
- chr6:32,549,940–32,589,848, 3 genes: RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr11:70,477,277–70,477,592, 1 gene (within-gene range 0–2): AP001271.1.
- chr14:44,392,531–44,567,467, 4 genes: AL161752.1, LINC02277, FSCB, AL356022.1.
- chr19:47,968,046–48,044,079, 3 genes: BSPH1, ELSPBP1, CABP5.
- chr19:48,061,371–48,064,945, 1 gene (within-gene range 0–1): PLA2G4C-AS1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 2,229 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:32,628,032–34,738,231, 22 genes, copy number 3: TTC27, MIR4765, LINC00486, LINC00486, Y_RNA, LTBP1, H2ACP2, AC019127.1, RNA5SP91, RNA5SP92, RASGRP3, RASGRP3-AS1, FAM98A, AC017050.1, ATP6V0E1P3, HNRNPA1P61, LINC01320, MYADML, SLC25A5P2, LINC01318, AC008170.1, AC073218.1.
- chr2:44,361,947–63,891,562, 293 genes, copy number 3–4 (broad region; genes not listed).
- chr2:69,960,089–85,310,387, 252 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:162,486,541–198,123,232, 631 genes, copy number 3–7 (broad region; genes not listed).
- chr7:37,032–2,614,733, 70 genes, copy number 3 (broad region; genes not listed).
- chr7:76,978,617–77,004,308, 1 gene, copy number 7 (within-gene range 2–7): DTX2P1.
- chr8:140,505,813–144,474,202, 164 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr8:144,495,458–145,066,685, 31 genes, copy number 3 (within-gene range 2–3): AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39, AC084125.3, Metazoa_SRP, AF186192.1, AF186192.2, AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr12:85,567,878–85,568,239, 1 gene, copy number 3: AC126471.1.
- chr14:104,724,229–104,795,751, 4 genes, copy number 3: ADSS1, SIVA1, AL583722.1, AKT1.
- chr14:104,815,449–104,858,836, 6 genes, copy number 3: AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1.
- chr16:33,808,778–33,810,767, 1 gene, copy number 3: AC136428.3.
- chr18:9,708,275–15,330,282, 176 genes, copy number 3 (broad region; genes not listed).
- chr18:22,088,060–23,486,603, 27 genes, copy number 3: AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1.
- chr18:25,818,234–27,247,188, 28 genes, copy number 4: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908.
- chr19:55,364,382–55,370,463, 1 gene, copy number 5: IL11.
- chr20:87,250–11,878,429, 256 genes, copy number 3 (broad region; genes not listed).
- chr20:30,484,925–36,085,703, 194 genes, copy number 3 (broad region; genes not listed).
- chr21:43,107,942–43,168,646, 1 gene, copy number 5 (within-gene range 1–5): AP001631.2.
- chr21:43,140,523–43,172,805, 3 genes, copy number 3–9: FRGCA, AP001631.1, CRYAA.
- chr22:49,718,053–50,801,309, 67 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 27,158. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
